Somatic mutation profile of tumor specimen TCGA-19-2621-01B (aliquot TCGA-19-2621-01B-01W-0922-08) from TCGA case TCGA-19-2621, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 83.3 years (30,429 days).
Specimen TCGA-19-2621-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6566ac57-9632-40d4-b65e-b13b757c7eca.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-19-2621-10A (Blood Derived Normal), aliquot TCGA-19-2621-10A-01W-0922-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/db1fbb5b-b437-40de-b0a8-acfe3e05ea84

The open-access MAF lists 89 somatic variants for this specimen: 58 protein-altering or splice-affecting, 29 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 29, Nonsense Mutation 4, Frame Shift Ins 2, Splice Site 2, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DYSF | c.4200dup p.I1401Hfs*8 | Frame Shift Ins (INS) | VAF 12/93 reads (13%) | catalogued as rs398123786; ClinVar: pathogenic; called by mutect2, varscan2
- PTEN | c.278A>G p.H93R | Missense Mutation (SNP) | VAF 89/104 reads (86%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs121909238, CM051214, COSV100910602, COSV64296545, COSV64296755; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AHNAK2 | c.14045G>A p.R4682H | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.193); catalogued as rs977034852, COSV100316751; called by muse, mutect2
- AKAP13 | c.2010C>A p.N670K | Missense Mutation (SNP) | VAF 30/409 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.122); catalogued as COSV100773423; called by muse, mutect2
- AP4E1 | c.361T>C p.S121P | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754250321; called by mutect2, varscan2
- ATP6V0A1 | c.2092C>T p.H698Y | Missense Mutation (SNP) | VAF 100/324 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.253); catalogued as COSV99230720, COSV99231836; called by muse, varscan2
- ATRX | c.787T>C p.W263R | Missense Mutation (SNP) | VAF 215/232 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM005475, COSV64880174; called by muse, mutect2, varscan2
- C2CD6 | c.677G>A p.G226E | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV99632471; called by muse, mutect2, varscan2
- CDC14A | c.736G>A p.D246N | Missense Mutation (SNP) | VAF 22/246 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100324736; called by muse, mutect2
- COA8 | c.491G>A p.R164H | Missense Mutation (SNP) | VAF 138/828 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.765); catalogued as rs756550363, COSV56029897; called by muse, mutect2, varscan2
- CRISP3 | c.311C>T p.A104V (on ENST00000371159 / NM_001368123.1; = p.A86V on NM_006061.4) | Missense Mutation (SNP) | VAF 34/197 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99538831; called by muse, mutect2, varscan2
- CST9L | c.38C>T p.A13V | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs760801440, COSV65407642, COSV65408515; called by muse, mutect2, varscan2
- CTCFL | c.1792G>A p.G598S | Missense Mutation (SNP) | VAF 156/423 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs947688028, COSV54774624, COSV99711958; called by muse, mutect2, varscan2
- DNM2 | c.850-1G>T p.X284_splice | Splice Site (SNP) | VAF 24/425 reads (6%) | catalogued as COSV99042637; called by muse, mutect2
- DST | c.6721A>T p.N2241Y | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.081); catalogued as COSV99753827; called by muse, mutect2, varscan2
- DUSP10 | c.1261G>A p.A421T | Missense Mutation (SNP) | VAF 247/732 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs747273512, COSV100100292; called by muse, mutect2, varscan2
- E2F2 | c.308C>T p.P103L | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV100674747; called by muse, varscan2
- E2F7 | c.1714G>A p.E572K | Missense Mutation (SNP) | VAF 72/281 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.516); catalogued as COSV59740636; called by muse, mutect2, varscan2
- EGFR | c.1871G>T p.C624F | Missense Mutation (SNP) | VAF 1051/1111 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28384376, COSV51863722, COSV99293015; called by muse, mutect2, varscan2
- FAM228A | c.173C>T p.P58L | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99722474; called by muse, mutect2
- FAM47A | c.1634C>T p.P545L | Missense Mutation (SNP) | VAF 61/73 reads (84%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs368188314, COSV60496012, COSV60498636; called by muse, mutect2, varscan2
- HIPK3 | c.3572C>T p.S1191F | Missense Mutation (SNP) | VAF 26/256 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); catalogued as rs1485801986; called by muse, mutect2
- HLF | c.161G>A p.S54N | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV56829777, COSV99872046; called by muse, mutect2, varscan2
- KAT6A | c.4754G>A p.S1585N | Missense Mutation (SNP) | VAF 51/115 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.12); catalogued as COSV55908257, COSV99704431; called by muse, mutect2, varscan2
- KIF16B | c.1048C>T p.R350C | Missense Mutation (SNP) | VAF 26/222 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755037043, COSV61702209; called by muse, mutect2, varscan2
- LIG3 | c.1331C>T p.S444L | Missense Mutation (SNP) | VAF 38/889 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs759246540, COSV52007055, COSV99252425; called by muse, mutect2
- LOXL3 | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 63/107 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs747365929, COSV99239578; called by muse, mutect2, varscan2
- LRRK2 | c.2302G>A p.E768K | Missense Mutation (SNP) | VAF 122/320 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100109718, COSV54146021; called by muse, mutect2, varscan2
- LTBP2 | c.2098C>T p.R700C | Missense Mutation (SNP) | VAF 15/21 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756749187, COSV100000049, COSV56210489; called by muse, varscan2
- MGARP | c.421G>C p.G141R | Missense Mutation (SNP) | VAF 89/230 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.246); catalogued as COSV101299202, COSV101299210; called by muse, mutect2, varscan2
- MYLK3 | c.1774G>A p.V592M | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as rs1207608535, COSV67364118; called by muse, mutect2, varscan2
- NDUFV2 | c.664C>T p.R222C | Missense Mutation (SNP) | VAF 34/49 reads (69%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs772693645, COSV100041034; called by muse, mutect2, varscan2
- NFYC | c.1362G>T p.Q454H (on ENST00000308733 / NM_001308114.1; = p.Q331H on NM_014223.5) | Missense Mutation (SNP) | VAF 51/113 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV100438347; called by muse, mutect2, varscan2
- NLRP13 | c.1648C>A p.L550I | Missense Mutation (SNP) | VAF 32/247 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100738130; called by muse, mutect2, varscan2
- NPAP1 | c.2792C>T p.P931L | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as COSV61512086; called by muse, mutect2, varscan2
- OSBPL1A | c.1092+1del p.X364_splice | Splice Site (DEL) | VAF 54/414 reads (13%) | catalogued as COSV100112557; called by mutect2, pindel, varscan2
- PHF20 | c.2413G>A p.E805K | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.045); catalogued as COSV100926557; called by muse, mutect2
- PIK3CD | c.112C>T p.R38C | Missense Mutation (SNP) | VAF 22/141 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.104); catalogued as rs765729544; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLEKHG6 | c.910G>A p.D304N | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99164146; called by muse, mutect2, varscan2
- POU3F2 | c.1144C>T p.Q382* | Nonsense Mutation (SNP) | VAF 43/68 reads (63%) | catalogued as COSV100099090; called by muse, mutect2, varscan2
- PTPRB | c.95C>T p.A32V | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.003); catalogued as rs759965483, COSV99716726; called by muse, mutect2, varscan2
- RGL4 | c.838T>A p.S280T | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.291); catalogued as COSV99318703; called by muse, mutect2
- RPAP1 | c.4036C>T p.L1346F | Missense Mutation (SNP) | VAF 85/272 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99778796; called by muse, mutect2, varscan2
- SLC17A5 | c.461C>T p.P154L | Missense Mutation (SNP) | VAF 39/296 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100867029; called by muse, mutect2, varscan2
- SLC35F4 | c.989T>A p.I330N (on ENST00000339762 / NM_001352015.2; = p.I294N on NM_001206920.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV100333682; called by muse, varscan2
- SLC5A7 | c.329G>T p.G110V | Missense Mutation (SNP) | VAF 69/258 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV99886496; called by muse, mutect2, varscan2
- SLC6A19 | c.571G>A p.G191S | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100443360; called by muse, mutect2
- TARS2 | c.495C>A p.F165L | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as COSV64694673, COSV64696817; called by muse, mutect2
- TESMIN | c.1358G>A p.W453* | Nonsense Mutation (SNP) | VAF 8/49 reads (16%) | catalogued as COSV99663516; called by muse, mutect2
- TLL2 | c.1673T>A p.F558Y | Missense Mutation (SNP) | VAF 13/143 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV63576071; called by mutect2, varscan2
- WDR27 | c.1295G>A p.G432E | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT tolerated (0.5); PolyPhen benign (0.01); catalogued as rs756110124, COSV100358559; called by muse, mutect2, varscan2
- ZNF335 | c.1165C>T p.P389S | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as COSV100532833; called by muse, mutect2, varscan2
- DAGLA | c.1583_1583+1insACCACCCC p.I529Pfs*47 | Frame Shift Ins (INS) | VAF 1414/1440 reads (98%) | called by mutect2, pindel*
- DNAH8 | c.446G>A p.W149* | Nonsense Mutation (SNP) | VAF 14/436 reads (3%) | called by muse, mutect2
- LSM3 | c.154A>C p.M52L | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.612); called by mutect2, varscan2
- MRM1 | c.1034C>T p.P345L | Missense Mutation (SNP) | VAF 23/347 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by muse, mutect2
- XPO6 | c.2404G>C p.E802Q | Missense Mutation (SNP) | VAF 38/216 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.382); called by mutect2, varscan2
- ZNF648 | c.1561C>T p.Q521* | Nonsense Mutation (SNP) | VAF 4/32 reads (13%) | called by muse, varscan2
- ARCN1 | c.156G>A p.E52= | Silent (SNP) | VAF 19/133 reads (14%) | catalogued as COSV99873578; called by muse, mutect2, varscan2
- BRCC3 | c.324T>C p.A108= | Silent (SNP) | VAF 25/27 reads (93%) | catalogued as COSV57462480; called by muse, mutect2, varscan2
- CCDC171 | c.2517G>T p.V839= | Silent (SNP) | VAF 21/66 reads (32%) | catalogued as COSV99900230; called by muse, mutect2, varscan2
- DGKD | c.1980C>T p.C660= (on ENST00000264057 / NM_152879.3; = p.C616= on NM_003648.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 29/60 reads (48%) | catalogued as rs762478279, COSV99895929; called by muse, mutect2, varscan2
- ENPEP | c.162G>A p.A54= | Silent (SNP) | VAF 104/306 reads (34%) | catalogued as rs761812461, COSV54447909; called by muse, mutect2, varscan2
- ERN2 | c.462C>A p.T154= | Silent (SNP) | VAF 87/198 reads (44%) | catalogued as COSV99891120; called by muse, mutect2, varscan2
- GEMIN5 | c.3642C>T p.S1214= | Silent (SNP) | VAF 8/72 reads (11%) | called by mutect2, varscan2
- ITGB6 | c.225C>T p.I75= | Silent (SNP) | VAF 69/393 reads (18%) | catalogued as rs370588403; ClinVar: likely benign; called by muse, mutect2, varscan2
- KLHDC3 | c.348C>T p.F116= | Silent (SNP) | VAF 18/286 reads (6%) | catalogued as COSV99763668; called by muse, mutect2
- LRP2 | c.8529C>T p.D2843= | Silent (SNP) | VAF 138/193 reads (72%) | catalogued as rs144486598; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRP5 | c.1860C>T p.P620= | Silent (SNP) | VAF 30/111 reads (27%) | catalogued as rs1461559460, COSV99591713; called by muse, mutect2, varscan2
- MMP17 | c.561C>T p.I187= | Silent (SNP) | VAF 23/37 reads (62%) | catalogued as rs1197252162, COSV100861890; called by muse, mutect2, varscan2
- PAQR4 | c.522C>T p.L174= | Silent (SNP) | VAF 9/15 reads (60%) | catalogued as COSV99233979; called by muse, mutect2, varscan2
- PDZRN4 | c.2337C>A p.T779= (on ENST00000402685 / NM_001164595.2; = p.T521= on NM_013377.4) | Silent (SNP) | VAF 59/184 reads (32%) | catalogued as COSV100114107; called by muse, mutect2, varscan2
- PLEKHG4 | c.3549G>A p.R1183= | Silent (SNP) | VAF 57/87 reads (66%) | catalogued as rs768209884, COSV100430816; called by muse, mutect2, varscan2
- REPS2 | c.816C>T p.P272= | Silent (SNP) | VAF 88/667 reads (13%) | catalogued as COSV100380957; called by muse, mutect2, varscan2
- SAMD9 | c.927T>A p.I309= | Silent (SNP) | VAF 17/62 reads (27%) | catalogued as COSV101180174; called by muse, mutect2, varscan2
- SCN1A | c.99G>A p.K33= | Silent (SNP) | VAF 11/245 reads (4%) | catalogued as COSV100319945; called by muse, mutect2
- SHROOM4 | c.294G>T p.P98= | Silent (SNP) | VAF 8/98 reads (8%) | catalogued as COSV99173205; called by muse, mutect2
- SLC1A7 | c.1194C>T p.Y398= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as rs377738768; called by muse, mutect2, varscan2
- SLX4 | c.2847A>G p.P949= | Silent (SNP) | VAF 22/57 reads (39%) | catalogued as COSV99567847; called by muse, mutect2, varscan2
- STXBP5 | c.2793G>A p.Q931= (on ENST00000321680 / NM_001127715.2; = p.Q895= on NM_139244.4) | Silent (SNP) | VAF 23/125 reads (18%) | catalogued as COSV99469807; called by muse, mutect2, varscan2
- UHRF1BP1 | c.3336G>A p.L1112= | Silent (SNP) | VAF 216/385 reads (56%) | catalogued as COSV99511708; called by muse, mutect2, varscan2
- USH2A | c.11925C>T p.A3975= | Silent (SNP) | VAF 10/122 reads (8%) | catalogued as COSV100232361; called by muse, mutect2
- USP9X | c.5922C>T p.I1974= | Silent (SNP) | VAF 32/186 reads (17%) | catalogued as COSV100198842; called by muse, varscan2
- YEATS4 | c.340C>T p.L114= | Silent (SNP) | VAF 8/61 reads (13%) | catalogued as COSV99923967, COSV99924053; called by muse, mutect2, varscan2
- ZNF383 | c.162G>A p.V54= | Silent (SNP) | VAF 20/312 reads (6%) | catalogued as COSV100776745; called by muse, mutect2
- ZNF407 | c.2577C>T p.A859= | Silent (SNP) | VAF 15/52 reads (29%) | catalogued as rs1290304359, COSV99995320; called by muse, mutect2, varscan2
- ZNF460 | c.789C>T p.R263= | Silent (SNP) | VAF 27/60 reads (45%) | catalogued as rs755790007, COSV64416051; called by muse, mutect2, varscan2
- IGKV1OR22-5 | n.141C>T | RNA (SNP) | VAF 155/450 reads (34%) | catalogued as rs371311353; called by muse, mutect2, varscan2
- MYO5C | c.450-1447G>A | Intron (SNP) | VAF 49/82 reads (60%) | catalogued as COSV99954455; called by muse, varscan2
